Gene-level copy-number profile of tumor specimen TCGA-56-A4BY-01A from TCGA case TCGA-56-A4BY, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.9 years (24,445 days).
Specimen TCGA-56-A4BY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2451896e-766c-4233-b09a-19ddf2c1febf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-A4BY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/05f7c7be-3bed-4dd3-8fed-cb4e44a8ad92

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 16,436; copy number 2: 35,202; copy number 3: 5,614; copy number 4: 2,417; copy number 5: 1; copy number 6: 76; copy number 7: 5; copy number 10: 3; copy number 15: 10; copy number 25: 4; copy number 27: 44; copy number 29: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-A4BY-01A-11D-A24C-01): tumor purity 0.45, ploidy 3.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 151 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:53,088,483–53,130,453, 1 gene, copy number 5 (within-gene range 1–5): RFT1.
- chr3:180,566,718–183,812,624, 67 genes, copy number 7–29 (within-gene range 4–29) (broad region; genes not listed).
- chr17:49,990,005–53,106,358, 80 genes, copy number 6–7 (broad region; genes not listed).
- chr17:53,353,427–53,439,721, 3 genes, copy number 10: AC005341.1, AC090079.1, AC090079.2.

Autosomal genes at a single copy (total copy number 1): 14,056. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
